TCGA case TCGA-BP-5189 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/23c7555b-7a37-415d-bda8-3588078a0c2e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Dead; Days to death: 822 days (2.3 years).

Diagnoses (4)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.7 years (22,156 days); Year of diagnosis: 2007; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G4; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Temsirolimus; Initial disease status: Progressive Disease; Days to treatment start: 661 days (1.8 years); Days to treatment end: 773 days (2.1 years); Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 794 days (2.2 years); Days to treatment end: 794 days (2.2 years); Number of cycles: 1; Route of administration: Intravenous.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 62.4 years (22,790 days); Days to diagnosis: 634 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 62.8 years (22,937 days); Days to diagnosis: 781 days (2.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 634 (post initial treatment): Progression or recurrence: Yes.
- Day 781 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 822 days (2.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Calcium: Low.
- Leukocytes: Elevated.
- Hemoglobin: Low.
- Platelets: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-5189-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-BP-5189-01A-01-BS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30.
  Slide TCGA-BP-5189-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-BP-5189-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-5189-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: No.
- Drug treatment 1: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2; Therapy regimen: Progression.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -4353.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy prostate cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 822 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 822 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 634 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BP-5189-01A-02D-1423-01): tumor purity 0.52, ploidy 1.92, whole-genome doublings 0.
